Somatic mutation profile of tumor specimen TCGA-EL-A3D4-01A (aliquot TCGA-EL-A3D4-01A-11D-A19J-08) from TCGA case TCGA-EL-A3D4, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 62.8 years (22,923 days).
Specimen TCGA-EL-A3D4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f4dbc08-c9e4-4818-a8e8-dfb7c7db8a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3D4-10A (Blood Derived Normal), aliquot TCGA-EL-A3D4-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f46dc88e-2b16-4978-a7ca-e8039c8afc2a

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR2B2 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV57579084; called by muse, mutect2
- RBM15B | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV60371087; called by muse, mutect2
- SLC25A45 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.688); catalogued as COSV53683218; called by muse, mutect2, varscan2
- SYCE1 | c.116_124del p.M39_Q41del (on ENST00000343131 / NM_001143764.3; = p.M3_Q5del on NM_130784.3) | In Frame Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- ERMP1 | c.912A>G p.S304= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV53036197; called by muse, mutect2, varscan2
- OR1N1 | c.609C>T p.T203= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs769711533, COSV59194998; called by muse, mutect2, varscan2
